Somatic mutation profile of tumor specimen TCGA-BC-A69H-01A (aliquot TCGA-BC-A69H-01A-11D-A30V-10) from TCGA case TCGA-BC-A69H, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 64.0 years (23,380 days).
Specimen TCGA-BC-A69H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96f24826-a27a-444d-8f48-9e88c0ab68e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A69H-10A (Blood Derived Normal), aliquot TCGA-BC-A69H-10A-01D-A30V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7c6c71e-2f81-4a73-ab37-b0c0c5f10135

The open-access MAF lists 88 somatic variants for this specimen: 65 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 20, Nonsense Mutation 4, Frame Shift Del 3, 3'UTR 1, RNA 1, Intron 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1159A>T p.N387Y | Missense Mutation (SNP) | VAF 62/163 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62711979; called by muse, mutect2, varscan2
- AC068580.4 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.046); catalogued as rs371522391, COSV52588844; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM23 | c.1702G>C p.D568H | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52224981; called by mutect2, varscan2
- ADCY3 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1333598498, COSV53170958; called by mutect2, varscan2
- AEBP1 | c.2204C>T p.S735L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.541); catalogued as rs745623681, COSV56260050; called by muse, mutect2, varscan2
- ALDH1L1 | c.1709T>C p.I570T | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV56417650; called by muse, mutect2, varscan2
- ALKBH7 | c.496A>C p.I166L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV55532654; called by muse, mutect2, varscan2
- ATP13A2 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.155); catalogued as COSV58702685; called by mutect2, varscan2
- ATP2B2 | c.1291A>G p.K431E (on ENST00000352432; = p.K397E on NM_001683.5) | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV59504428; called by muse, mutect2
- CCNJL | c.695A>C p.Y232S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57446198; called by muse, mutect2, varscan2
- CILP2 | c.1847C>A p.T616N | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV52278670; called by muse, mutect2, varscan2
- COL5A2 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as COSV66412985; called by muse, mutect2
- CPAMD8 | c.3035A>T p.Q1012L (on ENST00000651564; = p.Q965L on NM_015692.5) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV71597187, COSV71597441; called by muse, mutect2, varscan2
- CSMD1 | c.3815C>A p.P1272H (on ENST00000520002; = p.P1271H on NM_033225.6) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV59361738; called by muse, mutect2
- CYLD | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV61095890; called by muse, mutect2, varscan2
- DDX19B | c.1199A>C p.E400A | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.176); catalogued as COSV55365316; called by muse, mutect2, varscan2
- DSCAM | c.317A>T p.N106I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV68650190; called by muse, mutect2, varscan2
- FAM78A | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55992964; called by muse, mutect2, varscan2
- FASN | c.305G>A p.G102E | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60758812; called by muse, mutect2, varscan2
- FHDC1 | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV52602079; called by muse, mutect2, varscan2
- GLRA4 | c.518T>G p.L173R | Missense Mutation (SNP) | VAF 67/97 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV65456610; called by muse, mutect2, varscan2
- GRIN3A | c.466G>C p.A156P | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.676); catalogued as COSV62456837; called by muse, mutect2, varscan2
- GRXCR1 | c.173C>A p.S58Y | Missense Mutation (SNP) | VAF 56/88 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV67673605; called by muse, mutect2, varscan2
- IL5RA | c.836C>A p.T279K | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV56525525; called by muse, mutect2, varscan2
- IL9R | c.239G>T p.W80L | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV54901350; called by muse, mutect2, varscan2
- KAT6B | c.5282G>A p.S1761N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV54752336; called by muse, mutect2, varscan2
- KCNA5 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52907820; called by muse, varscan2
- MAP4K5 | c.1318G>T p.V440L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV50158348; called by muse, mutect2, varscan2
- MTMR7 | c.1211A>C p.E404A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51669156; called by muse, mutect2, varscan2
- MYO9B | c.2033A>G p.D678G | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV68281794; called by muse, mutect2, varscan2
- NEB | c.9839A>G p.Y3280C | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51444394; called by muse, mutect2, varscan2
- NLRX1 | c.2542G>A p.G848S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV52707679; called by muse, mutect2, varscan2
- NRXN2 | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.065); catalogued as COSV55460457; called by muse, mutect2, varscan2
- NUTM1 | c.727C>A p.P243T | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100412481; called by muse, varscan2
- NUTM1 | c.728C>A p.P243Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100412483; called by muse, varscan2
- PIK3R1 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV99149870; called by mutect2, varscan2
- PKP1 | c.2117T>C p.L706P | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55824038; called by muse, mutect2, varscan2
- PLAA | c.2010G>C p.Q670H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV68304928, COSV68305421; called by muse, mutect2, varscan2
- PORCN | c.1176C>T p.G392= (on ENST00000326194 / NM_203475.3; = p.G381= on NM_022825.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/10 reads (80%) | catalogued as rs1556975558, COSV52142104; called by muse, mutect2, varscan2
- PRMT1 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV55864219; called by muse, mutect2, varscan2
- PRPF8 | c.3670C>T p.R1224C | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); catalogued as COSV59266362; called by muse, mutect2, varscan2
- PXK | c.1346A>G p.H449R | Missense Mutation (SNP) | VAF 85/182 reads (47%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.967); catalogued as COSV57091831; called by muse, mutect2, varscan2
- RAB9B | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54588109; called by muse, mutect2, varscan2
- RTKN2 | c.1773G>T p.R591S | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59523806; called by muse, varscan2
- SERPINA6 | c.940G>T p.D314Y | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV58586735, COSV58588160; called by muse, mutect2, varscan2
- SH3BP2 | c.533A>G p.D178G | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV62554999; called by muse, mutect2, varscan2
- SHROOM4 | c.3316C>A p.P1106T | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV56794754; called by muse, mutect2, varscan2
- SNF8 | c.268A>T p.M90L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV51727467, COSV51727570; called by muse, mutect2, varscan2
- SORBS1 | c.2542G>A p.E848K (on ENST00000361941 / NM_001034954.2; = p.E498K on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs781314841, COSV53362750; called by muse, mutect2, varscan2
- STIP1 | c.824A>G p.Y275C | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59439422; called by mutect2, varscan2
- SVEP1 | c.767C>G p.A256G | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV57043842; called by muse, mutect2, varscan2
- SYNDIG1 | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV65238118; called by muse, mutect2, varscan2
- TAF1C | c.1299G>T p.Q433H | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58987478, COSV58988122; called by muse, mutect2, varscan2
- TEP1 | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV52997356; called by muse, mutect2, varscan2
- TMEM38B | c.725G>A p.W242* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as COSV65950884; called by muse, mutect2, varscan2
- ULK4 | c.839G>C p.W280S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57217988; called by muse, varscan2
- URB2 | c.507G>T p.L169F | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV51017640; called by muse, mutect2, varscan2
- USH2A | c.15332C>T p.T5111I | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV56412722; called by muse, mutect2, varscan2
- ZBTB32 | c.1160A>T p.Q387L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52891997; called by muse, mutect2, varscan2
- ZNF85 | c.1012G>T p.G338* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV60216498; called by muse, mutect2, varscan2
- BLOC1S3 | c.550_562del p.P184Afs*37 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | called by mutect2, pindel*
- HGS | c.882del p.M295Cfs*18 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel, varscan2
- KALRN | c.6415C>T p.Q2139* (on ENST00000360013 / NM_001024660.4; = p.Q442* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- SUN5 | c.535-2del p.X179_splice | Splice Site (DEL) | VAF 21/64 reads (33%) | called by mutect2, varscan2
- TP53 | c.288_298del p.V97Efs*48 | Frame Shift Del (DEL) | VAF 34/70 reads (49%) | called by mutect2, pindel, varscan2
- ALG3 | c.201A>G p.T67= | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV56613375; called by muse, mutect2, varscan2
- AMMECR1L | c.510G>A p.T170= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs1432663640, COSV55761546; called by muse, mutect2, varscan2
- ANTXR1 | c.987C>T p.I329= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs749173652, COSV58019050; called by muse, mutect2, varscan2
- ARHGEF18 | c.3315C>G p.L1105= (on ENST00000359920 / NM_001130955.2; = p.L1001= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/48 reads (54%) | catalogued as COSV60472537; called by muse, mutect2, varscan2
- EEA1 | c.2049A>G p.L683= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs751045550, COSV59288617; called by muse, mutect2, varscan2
- GPR158 | c.36C>A p.L12= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV66278304; called by muse, mutect2, varscan2
- HNRNPUL1 | c.807G>A p.V269= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV54565744; called by muse, mutect2, varscan2
- IQCE | c.864G>A p.K288= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV58080667; called by muse, mutect2, varscan2
- LAMA1 | c.4296T>C p.D1432= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV67541759; called by muse, mutect2, varscan2
- MGAM | c.3372C>T p.T1124= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV72075298; called by mutect2, varscan2
- OR52N4 | c.273C>G p.L91= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV57892045; called by muse, mutect2, varscan2
- P2RY1 | c.183A>G p.V61= | Silent (SNP) | VAF 15/143 reads (10%) | catalogued as COSV59310143; called by mutect2, varscan2
- PABPC5 | c.123T>A p.A41= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as COSV57042485; called by muse, mutect2, varscan2
- POU2F1 | c.2082T>C p.S694= (on ENST00000541643 / NM_001365848.1; = p.S717= on NM_002697.4) | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV54822407; called by muse, mutect2, varscan2
- PTOV1 | c.1026C>A p.I342= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs376020024; called by muse, mutect2, varscan2
- PTPRA | c.858G>A p.P286= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs142755718; called by muse, mutect2, varscan2
- RBM42 | c.78G>T p.P26= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV52549217; called by muse, mutect2, varscan2
- RBP3 | c.1131G>A p.Q377= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- RET | c.675G>A p.T225= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV60703631; called by muse, mutect2, varscan2
- WDR91 | c.186G>A p.R62= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as COSV60371384; called by muse, mutect2, varscan2
- EI24P4 | n.826A>T | RNA (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- FGFR3 | c.*802C>T | 3'UTR (SNP) | VAF 15/50 reads (30%) | catalogued as COSV53412837; called by muse, mutect2, varscan2
- RFX3 | c.1968+53A>T | Intron (SNP) | VAF 11/31 reads (35%) | catalogued as COSV56522353; called by muse, mutect2, varscan2
